Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MQ-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM AND HERNIA SAC, OMENTECTOMY AND HERNIORRHAPHY -

- A. FIBROADIPOSE TISSUE SAC WALL, NEGATIVE FOR METASTATIC CARCINOMA.
- B. OMENTUM, NEGATIVE FOR METASTATIC CARCINOMA.

PART 2: UTERUS (122 GRAMS), CERVIX AND BOTH ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. WELL-DIFFERENTIATED, ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE, NUCLEAR GRADE 2, FIGO GRADE 1, WITH EXTENSIVE NECROSIS AND MIXED INFLAMMATORY INFILTRATE.
- B. THE TUMOR INVADES 25% OF THE MYOMETRIAL THICKNESS (0.3 CM INVASION OF 1.2 CM THICK MYOMETRIUM).
- C. THE TUMOR INVOLVES 15% OF THE ENDOMETRIAL SURFACE.
- D. NO LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED.
- E. BACKGROUND ENDOMETRIUM SHOWS SIMPLE HYPERPLASIA AND A BENIGN ENDOMETRIAL POLYP.
- F. BENIGN PERITONEAL INCLUSION CYST (0.8 CM), ANTERIOR SEROSAL SURFACE OF UTERUS.
- G. THE MYOMETRIUM SHOWS MULTIPLE LEIOMYOMATA, UP TO 2.3 CM IN GREATEST DIMENSION.
- H. THE CERVIX IS NEGATIVE FOR CARCINOMA.
- I. CHRONIC CERVICITIS WITH REACTIVE EPITHELIAL ATYPIA.
- J. BENIGN ENDOCERVICAL POLYP.
- K. OVARY #1 SHOWS PHYSIOLOGIC CHANGES.
- L. FALLOPIAN TUBE #1 SHOWS MULTIPLE BENIGN PARATUBAL CYSTS.
- M. OVARY #2 SHOWS A BENIGN MUCINOUS CYSTADENOMA, 0.7 CM, AND INCLUSIONS CYSTS.
- N. FALLOPIAN TUBE #2 SHOWS BENIGN PARATUBAL CYSTS AND WALTHARD RESTS IN THE PARATUBAL SEROSA.

PART 3: LYMPH NODES, RIGHT EXTERNAL ILIAC, BIOPSY -

FIVE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/5).

ICD-0-3

PART 4: LYMPH NODES, RIGHT OBTURATOR, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

Adenocarcinoma, endometrioid, NOS

8380/3

PART 5: LYMPH NODES, LEFT EXTERNAL ILIAC, BIOPSY -

FOUR LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/4).

Site: Endometrium C54.1

PART 6: LYMPH NODES, LEFT OBTURATOR, BIOPSY -

FOUR LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/4).

hw 5/3/11

PART 7: LYMPH NODES, LEFT COMMON ILIAC, BIOPSY -

- A. ADIPOSE TISSUE, NO LYMPH NODE IDENTIFIED.
- B. NEGATIVE FOR METASTATIC CARCINOMA.

PART 8: LYMPH NODES, LEFT PERIAORTIC, BIOPSY -

- A. FIBROADIPOSE TISSUE, NO LYMPH NODE IDENTIFIED.
- B. NEGATIVE FOR METASTATIC CARCINOMA.

PART 9: LYMPH NODES, RIGHT COMMON ILIAC AND RIGHT PERIAORTIC, BIOPSY -

ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

COMMENT:

Companion pelvic wash negative negative for malignant cells.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

ARCHITECTURAL GRADE: Well differentiated (FIGO 1)

NUCLEAR GRADE: Well differentiated

TUMOR SIZE: Grade 2

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT: Maximum dimension: 4.2 cm

DEPTH OF INVASION**: Anterior endomyometrium: 30 %, Posterior endomyometrium: 0 %
ANGIOLYMPHATIC INVASION: Less than 1/2 thickness of myometrium

PRE-NEOPLASTIC CONDITIONS: No

OTHER: Simple endometrial hyperplasia without atypia

MITOTIC RATE: (epithelial, smooth muscle, others), Endometrial polyp, Leiomyoma

LYMPH NODES POSITIVE: Mitotic rate: 3 / 10 HPF

LYMPH NODES EXAMINED: Number of lymph nodes positive: 0

T STAGE, PATHOLOGIC: Total number of lymph nodes examined: 15

N STAGE, PATHOLOGIC: pT1b

M STAGE, PATHOLOGIC: pN0

FIGO STAGE: pMX

IB

Source: NCI Genomic Data Commons file 68f88da9-6af2-4a34-86ac-d5ad5fd39221 (TCGA-BG-A0MQ.3252AEB3-3B0D-4066-B18E-31096F928D63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).